Somatic mutation profile of tumor specimen 0DV2RA from CCDI case PBCIWY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.6 years (3,144 days).
Specimen 0DV2RA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a63389e9-50b9-4bac-a6e0-b0beaaf78826.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV2QT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05ad397c-365f-4e16-8557-c9be98291760

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPKB | c.1454C>G p.A485G | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.199); catalogued as rs766298121; called by muse, varscan2
- ZNF267 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs564973376; called by muse, varscan2
- RPAP1 | c.408G>A p.S136= | Silent (SNP) | VAF 96/351 reads (27%) | catalogued as rs371099309, COSV58539138; called by muse, varscan2
- PIEZO1 | c.6472-26G>A | Intron (SNP) | VAF 34/88 reads (39%) | catalogued as rs374146636; called by muse, varscan2
